Gene-level copy-number profile of tumor specimen TCGA-EB-A5KH-06A from TCGA case TCGA-EB-A5KH, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 57.4 years (20,963 days).
Specimen TCGA-EB-A5KH-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.06752264-6c29-4039-b0dc-a04edbfb516f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A5KH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3e662e31-33f6-450f-83ff-df0d85894819

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 6,269; copy number 2: 41,289; copy number 3: 10,005; copy number 4: 1,236; copy number 5: 303; copy number 6: 182; copy number 7: 97; copy number 8: 250; copy number 9: 72; copy number 10: 27; copy number 11: 16; copy number 12: 6; copy number 13: 27; copy number 15: 3; copy number 16: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A5KH-06A-11D-A27J-01): tumor purity 0.9, ploidy 2.22, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–22,214,672, 18 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 996 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:4,451,930–4,866,311, 1 gene, copy number 5 (within-gene range 3–5): AC106799.2.
- chr5:4,640,731–5,034,267, 6 genes, copy number 5 (within-gene range 2–5): AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1.
- chr5:7,980,146–10,777,062, 83 genes, copy number 7 (broad region; genes not listed).
- chr5:11,027,200–12,804,363, 6 genes, copy number 7: RNU6-429P, RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1.
- chr5:18,236,123–18,236,196, 1 gene, copy number 6: SNORD81.
- chr5:19,471,296–20,575,873, 1 gene, copy number 5 (within-gene range 2–5): CDH18.
- chr5:22,580,225–22,580,819, 1 gene, copy number 6: GCNT1P2.
- chr5:26,669,346–28,809,291, 15 genes, copy number 5: AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2.
- chr5:29,239,922–29,396,095, 2 genes, copy number 5 (within-gene range 2–5): AC112172.2, LINC02064.
- chr5:52,787,916–53,414,260, 14 genes, copy number 5–12: PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1, AC108114.1.
- chr5:53,883,942–54,310,582, 1 gene, copy number 6 (within-gene range 2–13): ARL15.
- chr5:54,286,194–54,957,846, 11 genes, copy number 9–13: AC008873.1, LINC01033, RPL37P25, HSPB3, SNX18, AC016583.1, AC016583.2, CSPG4BP, AC112198.1, AC112198.3, AC112198.2.
- chr5:64,718,148–64,768,691, 1 gene, copy number 11 (within-gene range 2–11): SREK1IP1.
- chr5:77,942,757–78,294,698, 5 genes, copy number 7 (within-gene range 2–7): AC108482.1, AC108482.2, AP3B1, AC024568.1, ATP6V1G1P6.
- chr5:78,485,215–78,770,021, 2 genes, copy number 9 (within-gene range 2–9): LHFPL2, HMGB1P21.
- chr5:82,765,404–82,778,586, 2 genes, copy number 9: AC008885.2, RPL5P16.
- chr5:82,840,155–83,875,821, 21 genes, copy number 10: MIR3977, LINC01338, AC108174.1, AC027338.2, ST13P12, AC027338.1, AC104118.1, TMEM167A, SCARNA18, XRCC4, AC094085.1, COQ10BP2, FTH1P9, VCAN, VCAN-AS1, HAPLN1, RN7SKP295, RNU6-620P, AC020899.1, RNU4-11P, ZP3P1.
- chr5:94,703,741–95,284,575, 5 genes, copy number 6–7 (within-gene range 2–7): MCTP1, AC008534.1, RPL7P18, AC008534.2, MCTP1-AS1.
- chr5:98,576,341–98,681,367, 2 genes, copy number 5: CTBP2P4, DDX18P4.
- chr5:101,581,830–101,582,128, 1 gene, copy number 7: RN7SL802P.
- chr5:102,131,007–108,382,098, 42 genes, copy number 9–16 (within-gene range 1–16): RNA5SP188, AC008948.1, SLCO4C1, RN7SKP68, SLCO6A1, AC094108.1, LINC00492, LINC00491, AC099487.1, AC099487.2, PAM, EIF3KP1, GIN1, PPIP5K2, AC011362.1, MACIR, AC010406.1, PDZPH1P, LINC02115, NUDT12, AC008505.1, LINC02163, RNU1-140P, RN7SL255P, AC099520.1, AC091931.1, AC099520.2, RNU6-334P, AC091987.1, RAB9BP1, RNA5SP189, AC027313.1, AC114940.1, AC114940.2, LINC01950, PSMC1P5, EFNA5, AC024587.2, AC024587.1, RN7SL782P, RN7SKP122, FBXL17.
- chr5:111,155,244–111,512,590, 6 genes, copy number 5–11: AC010468.2, RPS3AP21, CAMK4, AC010468.1, AC010275.1, STARD4.
- chr5:111,572,102–111,572,398, 2 genes, copy number 11: HMGN1P13, AC008967.1.
- chr5:111,912,508–113,595,285, 26 genes, copy number 5: NREP-AS1, EPB41L4A, EPB41L4A-AS1, SNORA13, AC010261.1, AC010261.2, AC104126.1, AC010265.1, EPB41L4A-DT, HMGB3P16, AC137549.1, LINC02200, APC, CBX3P3, RNU6-482P, AC008575.1, SRP19, REEP5, XBP1P1, ZRSR2P1, DCP2, MCC, AC079465.1, TSSK1B, RNU4ATAC13P, YTHDC2.
- chr5:115,031,273–118,266,267, 53 genes, copy number 5–11 (within-gene range 4–11): AC094104.2, AC094104.1, TRIM36, TRIM36-IT1, AC008494.2, PGGT1B, AC008494.3, AC008494.1, CCDC112, HMGN1P15, CTNNA1P1, AK3P4, AC008628.2, AC008628.1, CCT5P1, FEM1C, TICAM2, TMED7-TICAM2, AC010226.1, TMED7, AC008549.2, AC008549.1, H3P24, RNU2-49P, CDO1, ATG12, AP3S1, LINCADL, LVRN, DDX43P1, ARL14EPL, AC034236.1, AC034236.3, AC034236.2, COMMD10, RNU6-644P, HMGN2P27, AC018752.1, SEMA6A, SEMA6A-AS1, RPS14P8, SEMA6A-AS2, RPS17P2, LINC02214, AC010267.1, AC093534.1, AC093534.2, RPL35AP15, AC093295.1, LINC00992, AC114322.1, LINC02147, RPL7L1P4.
- chr5:121,575,848–122,834,543, 20 genes, copy number 8–10: RPL23AP44, AC106806.1, AC106806.2, FTMT, SRFBP1, LOX, AC010255.1, ZNF474, AC010255.2, ZNF474-AS1, AC113349.2, SNCAIP, AC113349.1, AC119150.1, AC119150.2, MGC32805, LINC02201, ARGFXP1, SNX2, AC008669.1.
- chr5:123,512,099–123,637,403, 2 genes, copy number 8 (within-gene range 1–8): CSNK1G3, KRT18P16.
- chr5:125,862,746–125,886,753, 2 genes, copy number 5: AC010587.2, AC010587.1.
- chr5:129,904,465–130,186,634, 1 gene, copy number 6 (within-gene range 1–6): CHSY3.
- chr5:130,114,409–131,797,063, 18 genes, copy number 6–15 (within-gene range 1–15): RNA5SP191, HSPA8P4, RNU7-53P, ARL2BPP4, AC005741.1, AC006525.1, AC113367.1, AC113367.3, AC113367.2, HINT1, LYRM7, CDC42SE2, AC004777.1, RAPGEF6, AC008695.1, AC008497.1, FNIP1, ACTBP4.
- chr5:134,648,785–136,193,162, 54 genes, copy number 9 (within-gene range 1–9): SEC24A, RNU6-1164P, RNU6-757P, CAMLG, DDX46, AC010301.1, C5orf24, AC006077.1, TXNDC15, PCBD2, AC006077.2, MTCYBP18, MTND6P4, MTND5P11, MTND4P12, MTND4LP30, AC008670.1, MTND3P25, CATSPER3, PITX1, C5orf66, AC008406.3, C5orf66-AS1, AC008406.2, AC008406.1, C5orf66-AS2, MACROH2A1, AC026691.1, DCANP1, TIFAB, AC022092.1, NEUROG1, AC034206.1, CXCL14, SLC25A48, SLC25A48-AS1, AC011431.1, MIR5692C1, AC114296.1, IL9, AC002428.2, AC002428.1, LECT2, FBXL21P, TGFBI, VTRNA2-1, Vault, SMAD5-AS1, AC009014.4, SMAD5, AC009014.2, AC009014.3, AC009014.1, SMIM32.
- chr5:136,214,048–136,222,159, 1 gene, copy number 9 (within-gene range 1–9): TRPC7-AS1.
- chr5:136,376,348–136,429,854, 3 genes, copy number 5: AC063980.1, HSPD1P18, HNRNPA1P13.
- chr5:149,141,483–149,944,793, 25 genes, copy number 6–11 (within-gene range 3–11): ABLIM3, AC012613.1, AC012613.2, AFAP1L1, AC131025.3, GRPEL2, GRPEL2-AS1, PCYOX1L, IL17B, AC131025.1, CARMN, AC131025.2, MIR143, MIR145, CSNK1A1, AC021078.1, RPL29P14, ARHGEF37, RNU6-588P, AC022100.1, U3, RN7SL868P, PPARGC1B, MIR378A, PDE6A.
- chr22:18,400,407–23,895,223, 388 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr22:24,006,305–25,729,294, 64 genes, copy number 5 (broad region; genes not listed).
- chr22:40,044,817–40,335,808, 1 gene, copy number 5 (within-gene range 4–5): TNRC6B.
- chr22:40,346,500–42,721,298, 104 genes, copy number 5 (broad region; genes not listed).
- chr22:43,400,331–43,513,727, 3 genes, copy number 6: LINC01639, MPPED1, BX546033.1.

Autosomal genes at a single copy (total copy number 1): 3,882. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
